Gene-level copy-number profile of tumor specimen ALCH-B4G7-TTP1-A from ALCHEMIST case ALCH-B4G7, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 71.6 years (26,135 days).
Specimen ALCH-B4G7-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 51712464-5f3d-4b22-a0f6-4251daf89292.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B4G7-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,726 have no estimate.
https://portal.gdc.cancer.gov/files/dc9b336a-62a6-45fa-9214-03e593f3dca2

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 25; copy number 1: 6,882; copy number 2: 48,550; copy number 3: 2,985; copy number 4: 332; copy number 5: 123.

Homozygous deletions (total copy number 0; autosomes only): 6 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:25,369,136–25,375,845, 1 gene: ARNILA.
- chr9:124,853,417–124,877,733, 3 genes: WDR38, RPL35, ARPC5L.
- chr9:132,161,676–132,244,526, 1 gene: NTNG2.
- chr14:104,724,229–104,747,325, 1 gene: ADSS1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 120 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr14:18,333,726–18,341,859, 1 gene, copy number 5: CR383658.1.
- chr19:38,433,691–40,629,818, 119 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 4,072. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
